Somatic mutation profile of tumor specimen TCGA-G4-6311-01A (aliquot TCGA-G4-6311-01A-11D-1719-10) from TCGA case TCGA-G4-6311, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 80.2 years (29,297 days).
Specimen TCGA-G4-6311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 551c387c-fa75-4527-a136-a67083c94906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6311-10A (Blood Derived Normal), aliquot TCGA-G4-6311-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1514e062-9315-4208-81db-5233dcbc6c84

The open-access MAF lists 156 somatic variants for this specimen: 110 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 42, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, Splice Site 2, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 80/209 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV52227217; called by muse, mutect2, varscan2
- ABCA6 | c.4265G>A p.C1422Y | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99445398; called by muse, mutect2, varscan2
- ANKFN1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV59455049; called by muse, mutect2, varscan2
- ANKRD30A | c.922C>T p.P308S (on ENST00000611781; = p.P252S on NM_052997.2) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.676); catalogued as rs796295970, COSV64616856; called by muse, varscan2
- ARHGAP35 | c.3641G>A p.R1214Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV68334145, COSV68335607; called by muse, mutect2, varscan2
- ASIC5 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV73332884; called by muse, mutect2, varscan2
- ATP12A | c.2067C>G p.S689R | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV99516735; called by muse, mutect2, varscan2
- BTAF1 | c.2633T>C p.I878T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV56437378; called by muse, mutect2
- BTAF1 | c.2635A>T p.K879* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV56432049, COSV56437392; called by muse, mutect2
- CARD10 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV52659099; called by muse, mutect2, varscan2
- CBX1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 65/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99847936; called by muse, mutect2, varscan2
- CD28 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs199647272, COSV60730477; called by muse, mutect2, varscan2
- CDON | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as rs143213791; called by muse, mutect2, varscan2
- CEP135 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99953962; called by muse, mutect2, varscan2
- CNGB3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs753353080, COSV60695108; called by muse, mutect2, varscan2
- COL21A1 | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.519); catalogued as COSV55173754; called by muse, mutect2, varscan2
- COL4A2 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs374304814; called by muse, mutect2, varscan2
- CPXM1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV66046338; called by muse, mutect2, varscan2
- CSMD3 | c.7802G>A p.R2601Q (on ENST00000297405 / NM_001363185.1; = p.R2497Q on NM_052900.3) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs564995042, COSV52100352, COSV52124954; called by muse, mutect2, varscan2
- CSMD3 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.763); catalogued as COSV52198582, COSV52266646; called by muse, mutect2, varscan2
- EIF2AK4 | c.3716A>G p.E1239G | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55472281; called by muse, mutect2, varscan2
- EIF4A3 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53921743; called by muse, mutect2, varscan2
- EPN1 | c.1076C>T p.P359L (on ENST00000270460 / NM_001321263.1; = p.P334L on NM_013333.3) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs771176714, COSV50041720; called by muse, mutect2, varscan2
- EXD3 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59811150; called by muse, mutect2, varscan2
- FAT3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538781318, COSV53082222, COSV53087184, COSV53104933; called by muse, mutect2, varscan2
- FEZF2 | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 151/350 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV51864051; called by muse, mutect2, varscan2
- GDAP1L1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV61155961; called by muse, mutect2
- GPR174 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985457789, COSV99337880; called by muse, mutect2, varscan2
- GRM7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559306156, COSV63159229, COSV63162440; called by muse, mutect2, varscan2
- HDAC9 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1013122276, COSV101286585, COSV67781242; called by muse, mutect2, varscan2
- HS3ST5 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as rs762269276, COSV100451539, COSV57147362; called by muse, mutect2, varscan2
- HSPA12A | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV65023400; called by muse, mutect2, varscan2
- HSPA4 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); catalogued as COSV59183184; called by muse, mutect2, varscan2
- HSPA6 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59062077; called by muse, mutect2, varscan2
- JAG1 | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54760742; called by muse, mutect2
- KCNA1 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV66836606; called by muse, mutect2, varscan2
- KIF21A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770064077, COSV62766767; ClinVar: benign; called by muse, mutect2, varscan2
- LRFN5 | c.173T>G p.L58W | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53269055; called by muse, mutect2, varscan2
- LTBP3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV57242316, COSV57242857; called by muse, mutect2, varscan2
- MMP20 | c.522A>G p.G174= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99497280; called by muse, varscan2
- MROH8 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.592); catalogued as COSV54118909, COSV54127574; called by muse, mutect2
- MROH8 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs776139405, COSV99456360; called by muse, mutect2, varscan2
- NBEA | c.1406T>C p.F469S | Missense Mutation (SNP) | VAF 79/589 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100075509, COSV100085466; called by muse, mutect2, varscan2
- NEB | c.12095G>T p.R4032L | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.15); catalogued as rs371681892, COSV51442975; called by muse, mutect2, varscan2
- OR2L2 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 92/576 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs774346957, COSV63558123; called by muse, mutect2, varscan2
- OR5AN1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58322595; called by muse, mutect2, varscan2
- OR8B3 | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs766069627, COSV100660332; called by muse, mutect2, varscan2
- PAGE2 | c.302C>G p.T101S | Missense Mutation (SNP) | VAF 134/234 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs748005733, COSV66596151; called by muse, mutect2, varscan2
- PARP12 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54936224; called by muse, mutect2
- PARP3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs371449435; called by muse, mutect2, varscan2
- PCDH11X | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV100006796; called by muse, mutect2, varscan2
- PCDH11X | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 137/502 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53491271; called by muse, mutect2, varscan2
- PCDH17 | c.3012C>A p.D1004E | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV100931365, COSV64978036; called by muse, mutect2, varscan2
- PCDH9 | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60576001; called by muse, mutect2, varscan2
- PKD1L1 | c.3679T>A p.F1227I | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56973393; called by muse, mutect2, varscan2
- PLPBP | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60240126; called by muse, mutect2
- POTEM | c.193T>G p.C65G | Missense Mutation (SNP) | VAF 89/538 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV101304474; called by muse, varscan2
- PSAP | c.1005+1G>A p.X335_splice | Splice Site (SNP) | VAF 24/147 reads (16%) | catalogued as rs113365744, COSV99818076; called by muse, mutect2, varscan2
- PTPRZ1 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV66442563; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs777219325, COSV51936345; called by muse, mutect2, varscan2
- RADX | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 110/198 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65319656; called by muse, mutect2, varscan2
- RBM14 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV59560155; called by muse, mutect2, varscan2
- RGS21 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1557983844, COSV69883402; called by muse, mutect2, varscan2
- RHOBTB1 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277027672, COSV61959561; called by muse, mutect2, varscan2
- RIMBP2 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs967487315, COSV55464433, COSV55485865; called by muse, mutect2, varscan2
- RNF207 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV65008094; called by muse, mutect2, varscan2
- ROBO2 | c.1715C>A p.A572E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59915814, COSV59929302; called by muse, mutect2, varscan2
- RPA2 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57878442; called by muse, mutect2, varscan2
- RYR2 | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63693407, COSV63703438; called by muse, mutect2, varscan2
- SCN3B | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs770801747, COSV54800582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.3767C>T p.S1256F | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1490792485, COSV71128239; called by muse, mutect2, varscan2
- SCN5A | c.2601G>T p.E867D | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.824); catalogued as COSV61135039, COSV99048708; called by muse, mutect2, varscan2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2
- SERTM1 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV59377263; called by muse, mutect2, varscan2
- SLC26A11 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100413251; called by muse, mutect2
- SPAG16 | c.1843G>T p.G615W | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100435001, COSV56968372; called by muse, mutect2, varscan2
- SPANXN2 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 166/279 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV65128352, COSV65128658; called by muse, mutect2, varscan2
- SPZ1 | c.782A>C p.H261P | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99697998; called by muse, mutect2, varscan2
- STAT5A | c.2048A>C p.Y683S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61807824; called by muse, mutect2, varscan2
- SYNE1 | c.16367T>G p.V5456G (on ENST00000367255 / NM_182961.4; = p.V5385G on NM_033071.3) | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV55056471; called by muse, mutect2, varscan2
- TAF1C | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV58988038; called by muse, mutect2, varscan2
- TBK1 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV59155940; called by muse, mutect2, varscan2
- TDRD6 | c.2260A>T p.N754Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV60177426; called by muse, mutect2, varscan2
- TGFBRAP1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs745998674, COSV51514786; called by muse, mutect2, varscan2
- TGIF1 | c.131C>A p.S44* (on ENST00000330513 / NM_001374396.1; = p.S64* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as COSV57908885; called by muse, mutect2, varscan2
- TINAG | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV52509023, COSV52513093; called by muse, mutect2
- TLR9 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62347909; called by muse, mutect2, varscan2
- TMEM248 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1174004528, COSV58578031; called by muse, mutect2, varscan2
- TMOD2 | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51045979; called by muse, mutect2, varscan2
- TNFSF15 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 34/172 reads (20%) | catalogued as rs1290489216, COSV100928295; called by muse, mutect2, varscan2
- TTC3 | c.2741-1G>C p.X914_splice | Splice Site (SNP) | VAF 47/172 reads (27%) | catalogued as COSV100694868; called by muse, mutect2, varscan2
- TTN | c.38983G>A p.D12995N (on ENST00000591111; = p.D5571N on NM_003319.4) | Missense Mutation (SNP) | VAF 78/480 reads (16%) | PolyPhen probably damaging (0.964); catalogued as COSV59956967, COSV60238306; called by muse, mutect2, varscan2
- UMOD | c.119C>G p.T40S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV56778161; called by muse, mutect2, varscan2
- USH2A | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 38/308 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56410060; called by muse, mutect2, varscan2
- VSIG8 | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV63653390; called by muse, mutect2, varscan2
- VWF | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752384122, COSV99777577; called by muse, mutect2
- WNK2 | c.4508G>T p.R1503M (on ENST00000297954 / NM_001282394.1; = p.R1466M on NM_006648.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV52953932; called by muse, mutect2, varscan2
- XKR7 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs997398608, COSV73812941; called by muse, mutect2, varscan2
- ZFHX4 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51481987, COSV99268629; called by muse, mutect2, varscan2
- ZNF334 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 80/757 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV61619651; called by muse, mutect2, varscan2
- ZNF436 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV58359105; called by muse, mutect2, varscan2
- ZNF595 | c.1472G>T p.W491L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.236); catalogued as COSV100227334; called by muse, mutect2, varscan2
- APC | c.147dup p.Q50Tfs*7 | Frame Shift Ins (INS) | VAF 35/220 reads (16%) | called by mutect2, pindel, varscan2
- SOX9 | c.768dup p.R257Afs*39 | Frame Shift Ins (INS) | VAF 24/177 reads (14%) | called by mutect2, pindel, varscan2
- TP53 | c.1005del p.E336Sfs*9 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.2920del p.E974Nfs*14 | Frame Shift Del (DEL) | VAF 34/355 reads (10%) | called by mutect2, pindel, varscan2
- ACACB | c.174G>T p.P58= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV58141955, COSV58146607; called by muse, mutect2, varscan2
- AL592490.1 | c.2652G>T p.V884= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as COSV101308051; called by muse, mutect2, varscan2
- AP3B2 | c.2661T>A p.P887= (on ENST00000261722; = p.P881= on NM_004644.5) | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV55612533; called by muse, mutect2, varscan2
- ATP10A | c.2103C>T p.A701= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs552984622, COSV63521043; called by muse, mutect2, varscan2
- BST1 | c.813C>T p.C271= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs373809408; called by muse, mutect2, varscan2
- C5orf24 | c.21C>T p.S7= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV57543202; called by muse, mutect2, varscan2
- CGAS | c.459C>T p.L153= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs757662937, COSV64808736; called by muse, mutect2, varscan2
- CSMD3 | c.8868C>A p.G2956= (on ENST00000297405 / NM_001363185.1; = p.G2787= on NM_052900.3) | Silent (SNP) | VAF 64/253 reads (25%) | catalogued as COSV52266613; called by muse, mutect2, varscan2
- EVPL | c.5376C>A p.I1792= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV56906926, COSV56914123; called by muse, mutect2, varscan2
- FAT3 | c.4563C>T p.A1521= | Silent (SNP) | VAF 59/241 reads (24%) | catalogued as rs762635092, COSV53102445, COSV53152681; called by muse, mutect2, varscan2
- FRY | c.6654C>T p.D2218= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV66575735; called by muse, mutect2, varscan2
- GAS6 | c.1164G>A p.A388= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs375788560; called by muse, mutect2, varscan2
- HHIP | c.1374A>G p.K458= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- IL6R | c.429G>A p.T143= | Silent (SNP) | VAF 46/300 reads (15%) | catalogued as rs373789486; called by muse, mutect2, varscan2
- ITGA4 | c.42C>T p.A14= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV52002687; called by muse, mutect2, varscan2
- JAGN1 | c.27G>A p.A9= | Silent (SNP) | VAF 73/251 reads (29%) | catalogued as rs764805098, COSV57061860; called by muse, mutect2, varscan2
- KCNK3 | c.1038G>A p.S346= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100256665, COSV57193821; called by muse, mutect2, varscan2
- KDM8 | c.510G>A p.A170= | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as rs763893122, COSV53731114; called by muse, mutect2, varscan2
- KRT33A | c.81C>T p.H27= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs201833052, COSV50365406; called by muse, mutect2, varscan2
- KSR2 | c.2388C>T p.N796= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as rs187354111; called by muse, mutect2, varscan2
- MAP3K7 | c.741T>C p.T247= | Silent (SNP) | VAF 37/178 reads (21%) | catalogued as COSV65225458; called by muse, mutect2, varscan2
- MAST2 | c.2610G>A p.P870= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs368953498; called by muse, mutect2, varscan2
- MAU2 | c.384G>A p.P128= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as rs776126180, COSV99448079; called by muse, mutect2, varscan2
- MCM10 | c.1791A>C p.P597= (on ENST00000484800 / NM_182751.3; = p.P596= on NM_018518.5) | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV66333045, COSV66335954; called by muse, mutect2, varscan2
- MCMBP | c.1638C>T p.S546= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs529084726, COSV63508890; called by muse, mutect2, varscan2
- NKX6-2 | c.705C>T p.D235= | Silent (SNP) | VAF 49/322 reads (15%) | catalogued as rs759933944, COSV63973937; called by muse, mutect2, varscan2
- OBP2B | c.174C>T p.G58= | Silent (SNP) | VAF 46/201 reads (23%) | catalogued as rs147483144; called by muse, mutect2, varscan2
- OBSCN | c.7470C>T p.C2490= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs553927346, COSV52739043; called by muse, mutect2, varscan2
- PCDHB12 | c.204T>A p.S68= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV99506505; called by muse, mutect2, varscan2
- PCDHGA3 | c.2283G>A p.A761= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as rs1324598241, COSV53946866; called by muse, mutect2, varscan2
- PRKN | c.258C>T p.D86= | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as rs778750300, COSV100628624, COSV58226637; called by muse, mutect2, varscan2
- PTCHD3 | c.153G>T p.P51= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV71256764, COSV71257170; called by muse, mutect2, varscan2
- PTPRJ | c.3534C>A p.T1178= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV69253675; called by muse, mutect2, varscan2
- PTPRS | c.2022C>A p.I674= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV53613152, COSV53630875, COSV53636955; called by muse, mutect2, varscan2
- SMAP1 | c.162C>T p.I54= | Silent (SNP) | VAF 53/345 reads (15%) | catalogued as rs1296315890, COSV57642940; called by muse, varscan2
- SQLE | c.1191A>T p.S397= | Silent (SNP) | VAF 36/298 reads (12%) | catalogued as COSV56281995; called by muse, mutect2, varscan2
- ST3GAL3 | c.1104G>A p.Q368= (on ENST00000361392 / NM_174964.4; = p.Q353= on NM_006279.5) | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV53518142; called by muse, mutect2, varscan2
- TMEM141 | c.180G>A p.L60= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV51567499; called by muse, mutect2, varscan2
- TNFRSF25 | c.123G>A p.K41= | Silent (SNP) | VAF 70/354 reads (20%) | catalogued as COSV61069262; called by muse, mutect2, varscan2
- TNR | c.1710C>T p.Y570= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs746969510, COSV54899996; called by muse, mutect2, varscan2
- TRPS1 | c.3225G>C p.A1075= (on ENST00000220888 / NM_001330599.2; = p.A1088= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/336 reads (12%) | catalogued as COSV55254779; called by muse, mutect2, varscan2
- ZNF714 | c.1545T>C p.T515= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99394811; called by muse, mutect2
- N4BP2L2 | chr13:32442954 A>G | 3'Flank (SNP) | VAF 116/808 reads (14%) | catalogued as COSV62634483; called by muse, mutect2, varscan2
- SSPOP | n.1839C>T | RNA (SNP) | VAF 10/55 reads (18%) | catalogued as rs761315893, COSV50486981; called by muse, mutect2, varscan2
- SSPOP | n.3036C>T | RNA (SNP) | VAF 15/40 reads (38%) | catalogued as rs536799190, COSV50488733; called by muse, mutect2, varscan2
- ZNF99 | c.*711C>A | 3'UTR (SNP) | VAF 16/98 reads (16%) | catalogued as COSV101233616, COSV68056556; called by muse, mutect2, varscan2
